Somatic mutation profile of tumor specimen TCGA-CH-5752-01A (aliquot TCGA-CH-5752-01A-11D-1576-08) from TCGA case TCGA-CH-5752, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,290 days).
Specimen TCGA-CH-5752-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4376785-b37e-486e-97c8-2cfbed22dc01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5752-10A (Blood Derived Normal), aliquot TCGA-CH-5752-10A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1909dd21-0e70-4afd-80fd-aa81e6f3d274

The open-access MAF lists 45 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 4, Splice Region 1, 5'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4B | c.3205A>G p.I1069V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.651); catalogued as rs1253251343, COSV51609648; called by muse, mutect2, varscan2
- ATP6V1A | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 58/176 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56364082; called by muse, mutect2, varscan2
- CCDC85A | c.1561C>A p.H521N | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1164910964, COSV68154847; called by muse, mutect2, varscan2
- COL6A5 | c.6092A>T p.D2031V (on ENST00000312481; = p.D2027V on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV55213456; called by muse, mutect2, varscan2
- CRMP1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV61480493; called by muse, mutect2, varscan2
- DHX40 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1368558325, COSV52066680, COSV52069686; called by muse, mutect2, varscan2
- EHHADH | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as COSV51632733; called by muse, mutect2, varscan2
- FAT3 | c.9967G>A p.A3323T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as rs572769099, COSV53118458; called by muse, mutect2, varscan2
- GALNT11 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 112/371 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.407); catalogued as rs202052372, COSV57428044; called by muse, mutect2, varscan2
- KMT2D | c.15326G>T p.C5109F | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM105471, COSV56477525; called by muse, mutect2, varscan2
- LHX5 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.54); catalogued as COSV55663937; called by muse, mutect2
- MARK3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53506254; called by muse, mutect2
- MSH3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as rs372073889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRG3 | c.2035G>A p.V679I (on ENST00000404547 / NM_001370084.1; = p.V655I on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.09); catalogued as rs143042604; called by muse, mutect2, varscan2
- OSER1 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as COSV54854417; called by muse, mutect2, varscan2
- PCDH11X | c.1817C>T p.T606M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs771338985, COSV53506109; called by muse, mutect2, varscan2
- PCNX4 | c.2660A>G p.D887G (on ENST00000406854 / NM_001330177.2; = p.D653G on NM_022495.5) | Missense Mutation (SNP) | VAF 14/437 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV58307292; called by muse, mutect2
- PHF20 | c.83+2T>G p.X28_splice | Splice Site (SNP) | VAF 4/88 reads (5%) | catalogued as COSV59188346; called by muse, mutect2
- PITPNC1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs780864654, COSV55447603; called by muse, mutect2, varscan2
- RYR1 | c.5427C>A p.D1809E | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.272); catalogued as COSV62107897; called by muse, mutect2, varscan2
- SPTA1 | c.4737G>A p.K1579= | Splice Region (SNP) | VAF 11/356 reads (3%) | catalogued as COSV63757962; called by muse, mutect2
- SRSF7 | c.341A>T p.H114L | Missense Mutation (SNP) | VAF 33/367 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57448182; called by muse, mutect2
- TJP1 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as COSV62045465; called by muse, mutect2, varscan2
- TMED9 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 31/102 reads (30%) | catalogued as rs753590322, COSV50354887; called by muse, mutect2, varscan2
- TPTE2 | c.899T>C p.F300S (on ENST00000400230 / NM_199254.2; = p.F223S on NM_130785.3) | Missense Mutation (SNP) | VAF 19/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55026745; called by muse, mutect2
- TRPM6 | c.600A>C p.R200S | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV62520445; called by muse, mutect2
- TTLL3 | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV59615472; called by muse, mutect2, varscan2
- TXNIP | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV65221251; called by muse, mutect2, varscan2
- ZNF518A | c.356T>G p.F119C | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60153012; called by muse, mutect2
- ARID2 | c.4329_4336del p.S1443Rfs*4 | Frame Shift Del (DEL) | VAF 69/360 reads (19%) | called by mutect2, pindel, varscan2
- CDKN1B | c.32del p.P11Lfs*31 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | called by mutect2, pindel, varscan2
- CYC1 | c.587del p.D196Afs*58 | Frame Shift Del (DEL) | VAF 17/156 reads (11%) | called by mutect2, pindel, varscan2
- DSCC1 | c.934_939del p.L312_V313del | In Frame Del (DEL) | VAF 54/212 reads (25%) | called by mutect2, pindel, varscan2
- KMT2C | c.11175_11176insAA p.E3726Kfs*20 | Frame Shift Ins (INS) | VAF 164/615 reads (27%) | called by mutect2, pindel, varscan2
- KMT2C | c.9101del p.P3034Lfs*4 | Frame Shift Del (DEL) | VAF 60/203 reads (30%) | called by mutect2, pindel, varscan2
- A1BG | c.480G>A p.E160= | Silent (SNP) | VAF 14/272 reads (5%) | catalogued as COSV54053099; called by muse, mutect2
- APOBEC3D | c.382C>T p.L128= | Silent (SNP) | VAF 11/150 reads (7%) | catalogued as COSV53328257; called by muse, mutect2
- CCDC115 | c.504C>G p.L168= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV52092631; called by muse, mutect2
- CUBN | c.4248G>A p.E1416= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV64724816; called by muse, mutect2
- MATN4 | c.1521G>A p.S507= (on ENST00000372754; = p.S466= on NM_003833.4) | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as rs1012757907, COSV61352607; called by muse, mutect2
- SACM1L | c.609A>G p.G203= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as COSV66614749; called by muse, mutect2
- TAS2R1 | c.466C>T p.L156= | Silent (SNP) | VAF 9/176 reads (5%) | catalogued as COSV66779306; called by muse, mutect2
- TLK1 | c.1860T>C p.G620= | Silent (SNP) | VAF 18/252 reads (7%) | catalogued as COSV62632519; called by muse, mutect2
- USP12 | c.816A>T p.T272= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV56659226; called by muse, mutect2, varscan2
- SUCO | chr1:172532691 C>T | 5'Flank (SNP) | VAF 6/94 reads (6%) | catalogued as COSV55270054; called by muse, mutect2
